Somatic mutation profile of tumor specimen 0DL0JD from CCDI case PBBYVT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.2 years (4,464 days).
Specimen 0DL0JD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b584e62-464d-4eed-8976-3092f8194f2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL0IW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5726bcb3-3373-473a-82ae-d73923f03614

The open-access MAF lists 24 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 7, Intron 5, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELFN1 | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 161/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1444533304, COSV70034431; called by muse, mutect2, varscan2
- NEUROG1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 184/422 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs754766630; called by muse, mutect2, varscan2
- PAX6 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 311/756 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as CD066386, COSV53795647; called by muse, mutect2, varscan2
- PPFIA3 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs754546714, COSV100494898, COSV61953215; called by muse, mutect2, varscan2
- ANKRD11 | c.3688C>T p.Q1230* | Nonsense Mutation (SNP) | VAF 385/962 reads (40%) | called by muse, mutect2, varscan2
- DDX3X | c.265_266dup p.S89Rfs*132 (on ENST00000399959; = p.S90Rfs*132 on NM_001356.5) | Frame Shift Ins (INS) | VAF 364/603 reads (60%) | called by mutect2, pindel, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/2038 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KIFAP3 | c.1545T>A p.D515E | Missense Mutation (SNP) | VAF 547/1581 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PTCH1 | c.3475_3502del p.L1159Wfs*23 | Frame Shift Del (DEL) | VAF 514/766 reads (67%) | called by mutect2, pindel*, varscan2
- TSHZ2 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 482/1164 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BCORL1 | c.2574G>A p.A858= | Silent (SNP) | VAF 148/173 reads (86%) | catalogued as rs199970788; called by muse, mutect2, varscan2
- DOCK1 | c.150G>A p.T50= | Silent (SNP) | VAF 394/1001 reads (39%) | catalogued as rs777561205, COSV99728548; called by muse, mutect2, varscan2
- FGFR4 | c.2157C>T p.Y719= | Silent (SNP) | VAF 80/220 reads (36%) | catalogued as rs746030739; called by muse, mutect2, varscan2
- GPR31 | c.195G>A p.A65= | Silent (SNP) | VAF 251/655 reads (38%) | catalogued as rs760218339; called by muse, mutect2, varscan2
- LRFN3 | c.1581C>T p.C527= | Silent (SNP) | VAF 123/316 reads (39%) | catalogued as rs564423039; called by muse, mutect2, varscan2
- MADD | c.894C>T p.H298= | Silent (SNP) | VAF 356/887 reads (40%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 57/1607 reads (4%) | called by muse, mutect2
- SNAP25 | c.345C>T p.S115= | Silent (SNP) | VAF 482/1403 reads (34%) | catalogued as COSV99654575, COSV99654751; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/353 reads (4%) | called by muse, mutect2
- CD44 | c.-71G>T | 5'UTR (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- EPHB2 | c.2852+86G>A | Intron (SNP) | VAF 129/309 reads (42%) | called by muse, mutect2, varscan2
- MKNK1 | c.637-89C>T | Intron (SNP) | VAF 15/38 reads (39%) | catalogued as rs185385697; called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- TBX2 | c.1686+59C>T | Intron (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
